Somatic mutation profile of tumor specimen TCGA-AA-3864-01A (aliquot TCGA-AA-3864-01A-01D-1981-10) from TCGA case TCGA-AA-3864, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage II; Age at diagnosis: 71.8 years (26,237 days).
Specimen TCGA-AA-3864-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 866d6c62-cfb3-4d79-b89d-2e68c5ee4738.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3864-10A (Blood Derived Normal), aliquot TCGA-AA-3864-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc795364-793e-4dab-818b-192b2ae97fbb

The open-access MAF lists 3,000 somatic variants for this specimen: 2,150 protein-altering or splice-affecting, 808 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,886, Silent 808, Nonsense Mutation 100, Frame Shift Del 87, Splice Site 26, Frame Shift Ins 25, Intron 20, Splice Region 18, RNA 12, 3'UTR 5, In Frame Del 5, 3'Flank 4.

Variants (750 of 3,000; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3787G>A p.G1263R | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs760376992, CM080019, COSV52746181; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALG8 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as rs200888240, COSV100219986, COSV55203161; ClinVar: pathogenic; called by muse, varscan2
- APC | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 183/516 reads (35%) | hotspot (GDC flag); catalogued as rs137854574, CM920035, COSV57321509; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 77/217 reads (35%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CACNA1A | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121908212, CM960238, COSV64189612; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDH23 | c.1949dup p.L651Sfs*13 | Frame Shift Ins (INS) | VAF 38/140 reads (27%) | catalogued as rs753886326; ClinVar: pathogenic; called by pindel, varscan2
- ERBB3 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 52/126 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778104039, COSV57252908; called by muse, mutect2, varscan2
- ERBB3 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 21/60 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1035001455, COSV57246372; called by muse, mutect2, varscan2
- FBN1 | c.5540G>A p.C1847Y | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555396185, COSV100354115; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FKTN | c.1106del p.F369Sfs*37 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | catalogued as rs750176716; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 11/84 reads (13%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- HGSNAT | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 174/446 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766835582, CM065258, COSV52817500, COSV99034812; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- INPPL1 | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs397514511, CM130300, COSV99995920; ClinVar: pathogenic; called by muse, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 82/223 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LSM14A | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 67/180 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV70884731; called by muse, mutect2, varscan2
- LZTR1 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 109/357 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs587777177, CM140924, COSV99301371; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PEX1 | c.2992C>T p.R998* | Nonsense Mutation (SNP) | VAF 88/203 reads (43%) | catalogued as rs61750428, CM022826, COSV99951906; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PEX6 | c.2578C>T p.R860W | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs61753230, CM091387, COSV99769527; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 70/169 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.1261C>T p.R421* | Nonsense Mutation (SNP) | VAF 63/175 reads (36%) | catalogued as rs587778617, CM164326, COSV56224693, COSV99764517; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 140/375 reads (37%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 51/155 reads (33%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- SLC4A1 | c.1462G>A p.V488M | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs28931584, CM971385, COSV52258208; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.914C>A p.P305Q | Missense Mutation (SNP) | VAF 57/160 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100053399, COSV51014574; called by muse, mutect2, varscan2
- TNNT2 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121964856, CM951218, CM961373, COSV52665973, COSV99372082; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USH2A | c.15143C>T p.A5048V | Missense Mutation (SNP) | VAF 120/371 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.116); catalogued as rs748393788, COSV100229977; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- USP9X | c.7440dup p.A2481Sfs*17 | Frame Shift Ins (INS) | VAF 46/89 reads (52%) | catalogued as rs774054468; ClinVar: uncertain significance / not provided / pathogenic; called by mutect2, varscan2
- ZBTB24 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as rs387907104, CM114080, COSV57781884; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAR2 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs769126744, COSV100299172; called by muse, mutect2, varscan2
- AARS2 | c.2319G>T p.K773N | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99771273; called by muse, mutect2, varscan2
- AASS | c.2413G>A p.D805N | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.88); catalogued as COSV100741687; called by muse, mutect2, varscan2
- ABCA13 | c.8572G>A p.G2858R | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.185); catalogued as rs758362582, COSV71290211; called by muse, mutect2, varscan2
- ABCA3 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs775752104, COSV57053624; called by muse, mutect2
- ABCA4 | c.6439G>A p.A2147T | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs966835207, COSV100933037; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA8 | c.1720A>G p.T574A | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99284976; called by muse, mutect2
- ABCB1 | c.3104T>C p.V1035A | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV99712288; called by muse, mutect2, varscan2
- ABCB10 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 89/183 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs755725401, COSV100747857; called by muse, mutect2, varscan2
- ABCB5 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 107/302 reads (35%) | catalogued as rs753647911, COSV51706888; called by muse, mutect2, varscan2
- ABCB5 | c.2908del p.E970Kfs*29 (on ENST00000404938 / NM_001163941.2; = p.E525Kfs*29 on NM_178559.6) | Frame Shift Del (DEL) | VAF 11/108 reads (10%) | catalogued as rs754572690; called by mutect2, pindel, varscan2
- ABCC10 | c.205C>T p.R69* (on ENST00000372530 / NM_001198934.2; = p.R26* on NM_033450.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 68/160 reads (43%) | catalogued as rs142310490; called by muse, mutect2, varscan2
- ABCC2 | c.2152A>C p.N718H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100966405; called by muse, mutect2, varscan2
- ABCC5 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751998938, COSV99656497; called by muse, mutect2, varscan2
- ABCC6 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs371804833, COSV99228094; called by muse, mutect2
- ABHD10 | c.716G>A p.C239Y | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99844919; called by muse, mutect2, varscan2
- ABLIM2 | c.1582G>A p.A528T (on ENST00000341937 / NM_001130084.2; = p.A562T on NM_001130083.2) | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV99589084; called by muse, mutect2, varscan2
- ABO | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs370138477; called by muse, mutect2, varscan2
- ABO | c.362C>A p.A121D | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101505933; called by muse, mutect2, varscan2
- ABRACL | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 83/241 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as rs779344089, COSV100866320; called by muse, mutect2, varscan2
- AC004832.3 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.108); catalogued as rs112718421; called by muse, mutect2, varscan2
- AC008397.2 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286059404, COSV99441272; called by muse, mutect2, varscan2
- AC011462.1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.319); catalogued as rs536540966, COSV54195750; called by muse, mutect2, varscan2
- AC068580.4 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs779278368, COSV52588134; ClinVar: uncertain significance / likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AC231657.3 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as COSV100540123; called by muse, mutect2, varscan2
- ACACB | c.1038G>A p.A346= | Splice Region (SNP) | VAF 125/311 reads (40%) | catalogued as rs575445770, COSV100622403, COSV58137137; called by muse, mutect2, varscan2
- ACADSB | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772084235, COSV62550837; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAP2 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs779591643, COSV58754703; called by muse, mutect2, varscan2
- ACIN1 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.196); catalogued as COSV99399136; called by muse, mutect2, varscan2
- ACOT7 | c.1090C>T p.R364W (on ENST00000377855 / NM_181864.3; = p.R354W on NM_007274.4) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781024703, COSV64111974; called by muse, mutect2, varscan2
- ACOT8 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs779680625, COSV99467380; called by muse, varscan2
- ACOT9 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 58/82 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV60538191; called by muse, mutect2, varscan2
- ACRBP | c.1576G>A p.V526I | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs756765669, COSV99975951; called by muse, mutect2, varscan2
- ACTL9 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs781963592, COSV61005716; called by muse, mutect2, varscan2
- ACTN1 | c.2548C>T p.R850C | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs148344567; called by muse, mutect2, varscan2
- ACTRT2 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs1292986662, COSV65758955; called by muse, mutect2, varscan2
- ACYP2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs756400058, COSV100336330; called by muse, varscan2
- ADA | c.754C>A p.L252M | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV100596081; called by muse, mutect2, varscan2
- ADAD1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 107/304 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV99635164; called by muse, mutect2, varscan2
- ADAM11 | c.2150C>T p.T717M | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.335); catalogued as rs374608514, COSV52346234; called by muse, varscan2
- ADAM19 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752116586, COSV57423104; called by muse, mutect2, varscan2
- ADAM9 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 118/287 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs138482520; called by muse, mutect2, varscan2
- ADAMTS2 | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as rs367549580, COSV52387833; called by muse, mutect2, varscan2
- ADAMTS20 | c.3295C>T p.R1099* | Nonsense Mutation (SNP) | VAF 23/78 reads (29%) | catalogued as rs757261794, COSV101166089; called by muse, mutect2, varscan2
- ADAMTS5 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV99537105; called by muse, varscan2
- ADAMTS6 | c.1652G>A p.G551D | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs775821305; called by muse, mutect2, varscan2
- ADARB2 | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1214688837, COSV101186678; called by muse, mutect2, varscan2
- ADCY1 | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338700641, COSV52040140; called by muse, mutect2, varscan2
- ADCY4 | c.1850G>A p.S617N | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV100156227; called by muse, mutect2, varscan2
- ADCY7 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs545059286, COSV54271135; called by muse, varscan2
- ADD2 | c.1373C>A p.P458H | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.497); catalogued as COSV100034844; called by muse, mutect2, varscan2
- ADD2 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.372); catalogued as rs370464708; called by muse, mutect2, varscan2
- ADGRB1 | c.1749G>T p.E583D | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.167); catalogued as COSV60092837; called by muse, mutect2, varscan2
- ADGRB2 | c.4280C>T p.P1427L | Missense Mutation (SNP) | VAF 106/262 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.09); catalogued as rs146789434, COSV57070094; called by muse, mutect2, varscan2
- ADGRE5 | c.59C>A p.T20N | Missense Mutation (SNP) | VAF 105/415 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV99662662; called by muse, mutect2, varscan2
- ADGRF5 | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778170741, COSV99345020; called by muse, mutect2, varscan2
- ADGRG1 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs770060105, COSV101113364; called by muse, mutect2, varscan2
- ADGRG6 | c.3203G>A p.R1068H | Missense Mutation (SNP) | VAF 209/575 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425955493, COSV99746024; called by muse, mutect2, varscan2
- ADGRL4 | c.1240T>G p.S414A | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0.235); catalogued as COSV100875647, COSV66060237; called by muse, mutect2, varscan2
- ADGRV1 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs372147148, COSV101315539; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.2663G>A p.G888D | Missense Mutation (SNP) | VAF 91/324 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101315541, COSV101316400; called by muse, mutect2, varscan2
- ADHFE1 | c.715A>C p.S239R | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs553493479, COSV52553814; called by muse, mutect2, varscan2
- ADK | c.778G>T p.E260* (on ENST00000286621; = p.E243* on NM_001123.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/303 reads (9%) | catalogued as COSV99691723; called by muse, mutect2
- ADORA2A | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100417851; called by muse, mutect2, varscan2
- ADORA3 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 102/247 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs778435396, COSV53985180; called by muse, mutect2, varscan2
- AFF3 | c.2966A>G p.H989R | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417990; called by muse, mutect2, varscan2
- AFF3 | c.1924C>T p.R642C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs780233607, COSV57876679; called by muse, mutect2, varscan2
- AGAP1 | c.1726C>T p.R576W (on ENST00000304032 / NM_001037131.3; = p.R523W on NM_014914.5) | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58326271; called by muse, mutect2, varscan2
- AGAP6 | c.1633C>T p.R545C (on ENST00000374056 / NM_001365867.1; = p.R568C on NM_001077665.2) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs782697526, COSV65017635; called by muse, mutect2, varscan2
- AGBL4 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233179501, COSV61894693; called by muse, mutect2, varscan2
- AGO2 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV55046834; called by muse, mutect2, varscan2
- AGO2 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV55046708; called by muse, mutect2, varscan2
- AGPAT1 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100421523; called by muse, mutect2, varscan2
- AGPAT4 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.373); catalogued as rs1158616160, COSV57245733; called by muse, mutect2, varscan2
- AHCYL1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs756700510, COSV100779447; called by muse, mutect2, varscan2
- AHCYL2 | c.1459G>A p.V487M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs1380181258, COSV100272969; called by muse, mutect2, varscan2
- AHDC1 | c.2594G>A p.R865Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as rs754239206, COSV99898937; called by muse, mutect2, varscan2
- AHSG | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs766181399, COSV56607693; called by muse, varscan2
- AKAP12 | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99482546; called by muse, mutect2, varscan2
- AKAP12 | c.2153G>A p.G718E | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV99482554; called by muse, mutect2, varscan2
- AKAP9 | c.5641C>T p.R1881* (on ENST00000359028; = p.R1849* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 44/123 reads (36%) | catalogued as COSV100661970; called by muse, mutect2, varscan2
- AKR1B1 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs1380748552, COSV53646649; called by muse, mutect2, varscan2
- AL136295.1 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs138817054; called by muse, mutect2, varscan2
- AL136295.1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs757711177, COSV55779531; called by muse, mutect2, varscan2
- AL441992.2 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs377314110; called by muse, mutect2, varscan2
- ALAS2 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 92/132 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430414100, COSV58193081; called by muse, mutect2, varscan2
- ALCAM | c.1217_1218del p.E406Vfs*19 | Frame Shift Del (DEL) | VAF 112/410 reads (27%) | catalogued as rs1189829981; called by pindel, varscan2
- ALDH1A2 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 116/286 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs376965202; called by muse, mutect2, varscan2
- ALDH1L1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1158482557, COSV56413602; called by muse, mutect2, varscan2
- ALDH2 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs1276830351, COSV55665518; called by muse, mutect2, varscan2
- ALDH4A1 | c.1469T>C p.V490A | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV99311577; called by muse, mutect2, varscan2
- ALDH4A1 | c.249+2T>C p.X83_splice | Splice Site (SNP) | VAF 14/92 reads (15%) | catalogued as COSV99311580; called by muse, mutect2
- ALG5 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1332833799, COSV99523532, COSV99523778; called by muse, mutect2, varscan2
- ALPI | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs151137290; called by muse, mutect2, varscan2
- ALPK3 | c.2150C>A p.P717H | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV51935962; called by muse, mutect2, varscan2
- ALS2 | c.3848G>A p.G1283E | Missense Mutation (SNP) | VAF 89/263 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99968848; called by muse, mutect2, varscan2
- ALS2 | c.3137A>T p.D1046V | Missense Mutation (SNP) | VAF 126/361 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs982635177, COSV99968850; called by muse, mutect2, varscan2
- AMBRA1 | c.3581C>T p.T1194M (on ENST00000458649 / NM_001367468.1; = p.T1104M on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs762502501, COSV54048512; called by muse, mutect2, varscan2
- AMER1 | c.295C>A p.L99M | Missense Mutation (SNP) | VAF 80/107 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV57668736; called by muse, mutect2, varscan2
- AMER3 | c.1430A>G p.D477G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100366061; called by muse, mutect2
- AMIGO1 | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs757591436, COSV100880979; called by muse, mutect2, varscan2
- AMMECR1L | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs750132896, COSV55760831; called by muse, mutect2, varscan2
- AMOTL1 | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs376912369; called by muse, mutect2, varscan2
- AMOTL1 | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as rs762133686, COSV58565468, COSV58570221; called by muse, mutect2, varscan2
- ANGPT2 | c.490T>C p.S164P | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100290644; called by muse, mutect2, varscan2
- ANK1 | c.3512G>A p.R1171H | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs767553149, COSV55899058; called by muse, mutect2, varscan2
- ANK2 | c.4555G>A p.A1519T | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs200920714, COSV99999029; called by muse, mutect2, varscan2
- ANK2 | c.5588C>T p.T1863M | Missense Mutation (SNP) | VAF 75/222 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs536962908, COSV52152126; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.5917C>T p.P1973S | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.242); catalogued as rs1316622536, COSV100000043; called by muse, mutect2, varscan2
- ANKDD1A | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 61/319 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV100132599; called by muse, mutect2, varscan2
- ANKFN1 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as rs376046142; called by muse, varscan2
- ANKFY1 | c.2816G>A p.R939H (on ENST00000341657 / NM_001330063.2; = p.R940H on NM_016376.5) | Missense Mutation (SNP) | VAF 100/275 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs1402085605, COSV100492315; called by muse, mutect2, varscan2
- ANKMY2 | c.1078C>A p.L360M | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100186893; called by muse, mutect2, varscan2
- ANKRD11 | c.5972C>A p.P1991Q | Missense Mutation (SNP) | VAF 87/195 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV99968466; called by muse, mutect2, varscan2
- ANKRD11 | c.3473C>T p.A1158V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.006); catalogued as COSV99968471; called by muse, mutect2, varscan2
- ANKRD16 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.548); catalogued as COSV99510355; called by muse, mutect2, varscan2
- ANKS1B | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269579871, COSV61345301; called by muse, mutect2, varscan2
- ANO3 | c.1799T>A p.V600D | Missense Mutation (SNP) | VAF 102/269 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV99880981; called by muse, mutect2, varscan2
- ANO3 | c.2372C>T p.A791V | Missense Mutation (SNP) | VAF 102/290 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1195680183, COSV99880986; called by muse, mutect2, varscan2
- ANP32A | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 130/363 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV99142978; called by muse, mutect2, varscan2
- ANXA4 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs770362785, COSV67848640; called by muse, varscan2
- ANXA5 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1039882471, COSV99634214; called by muse, mutect2, varscan2
- ANXA6 | c.778C>A p.L260I | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62905734; called by muse, mutect2, varscan2
- AOC2 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99513519; called by muse, mutect2, varscan2
- AOX1 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 250/693 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs752882911, COSV65981708; called by muse, mutect2, varscan2
- AOX1 | c.1958_1960del p.F653del | In Frame Del (DEL) | VAF 68/223 reads (30%) | catalogued as rs770755070; called by mutect2, pindel, varscan2
- AP2A2 | c.1142A>G p.D381G | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100172557; called by muse, mutect2, varscan2
- AP3B2 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750333792, COSV55606279; called by muse, varscan2
- APBA1 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV99595530; called by muse, mutect2, varscan2
- APBA2 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.997); catalogued as rs903813670, COSV68790221; called by muse, mutect2
- APBB3 | c.898C>T p.P300S (on ENST00000357560 / NM_133173.2; = p.P307S on NM_006051.3) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100021174; called by muse, mutect2, varscan2
- APC | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 37/110 reads (34%) | catalogued as rs1314843920, CM013690, COSV57335557; called by muse, mutect2, varscan2
- APC | c.4196G>A p.R1399H | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1431515214, COSV57339858, COSV57361062; called by muse, varscan2
- APPL1 | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 60/184 reads (33%) | catalogued as rs1177602938, COSV55702989; called by muse, mutect2, varscan2
- ARAF | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 42/56 reads (75%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); catalogued as COSV51693684, COSV51694693; called by muse, mutect2, varscan2
- ARF4 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.052); catalogued as rs777379437, COSV100327128; called by muse, mutect2, varscan2
- ARFGEF1 | c.5084C>T p.A1695V | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.261); catalogued as rs140098688; called by muse, mutect2
- ARHGAP20 | c.3007G>A p.G1003S | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs202001398, COSV52810364; called by muse, mutect2, varscan2
- ARHGAP20 | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs1424536606, COSV99503233; called by muse, mutect2, varscan2
- ARHGAP44 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99310178; called by muse, mutect2, varscan2
- ARHGEF10 | c.3940G>A p.V1314I (on ENST00000398564; = p.V1289I on NM_014629.4) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100033990; called by muse, mutect2, varscan2
- ARHGEF12 | c.3042T>A p.D1014E | Missense Mutation (SNP) | VAF 18/596 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100754694; called by muse, mutect2
- ARHGEF17 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs201544882, COSV99734974; called by muse, mutect2, varscan2
- ARHGEF37 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552298903, COSV100381940, COSV61368262; called by muse, mutect2, varscan2
- ARHGEF37 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs200439928, COSV100381830; called by muse, mutect2, varscan2
- ARHGEF37 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs767920437, COSV100381944; called by muse, mutect2, varscan2
- ARID1B | c.4916C>T p.T1639M | Missense Mutation (SNP) | VAF 161/470 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1215965074, COSV51671801; called by muse, mutect2, varscan2
- ARID3A | c.1687G>A p.G563S | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs779323045, COSV99708267; called by muse, varscan2
- ARIH1 | c.1342C>T p.H448Y | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.759); catalogued as COSV101158613; called by muse, mutect2, varscan2
- ARMC1 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 83/189 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs901933645, COSV52535300; called by muse, mutect2, varscan2
- ARNTL | c.1184C>T p.T395M (on ENST00000403290 / NM_001297719.2; = p.T394M on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs370345058; called by muse, mutect2, varscan2
- ARPIN | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV62590596; called by muse, mutect2, varscan2
- ARSF | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 85/105 reads (81%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs182964743, COSV100839436; called by muse, mutect2, varscan2
- ARSH | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 75/96 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs145391454, COSV101139759; called by muse, mutect2, varscan2
- ART5 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as rs746090717, COSV51704244; called by muse, mutect2, varscan2
- ASB1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as rs150540319; called by muse, mutect2, varscan2
- ASB5 | c.685A>C p.K229Q | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.724); catalogued as COSV99641336; called by muse, mutect2, varscan2
- ASB6 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs145932765, COSV99475571; called by muse, mutect2, varscan2
- ASB6 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs774218305, COSV99475614; called by muse, mutect2, varscan2
- ASCC3 | c.2024G>A p.R675H | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as rs370833839; called by muse, varscan2
- ASH1L | c.2119A>G p.K707E | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV64206043; called by muse, mutect2, varscan2
- ASIC1 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs767028389, COSV57316600; called by muse, mutect2, varscan2
- ASIC4 | c.1135C>A p.L379M (on ENST00000347842 / NM_182847.3; = p.L398M on NM_018674.6) | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61732667; called by muse, mutect2, varscan2
- ASNSD1 | c.1553T>C p.L518S | Missense Mutation (SNP) | VAF 127/320 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99641001; called by muse, mutect2, varscan2
- ASPH | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 100/286 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as rs1202877763, COSV62860407; called by muse, varscan2
- ASPM | c.4309C>T p.R1437C | Missense Mutation (SNP) | VAF 181/491 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.962); catalogued as rs371861473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASTL | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV60903866; called by muse, mutect2, varscan2
- ASXL1 | c.3989C>A p.P1330H | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100037941; called by muse, mutect2, varscan2
- ASXL3 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as rs374451313; called by muse, varscan2
- ATAD5 | c.4984C>A p.L1662I | Missense Mutation (SNP) | VAF 117/310 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.265); catalogued as COSV100429697, COSV100429859; called by muse, mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 35/125 reads (28%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATG2A | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101033913; called by muse, mutect2, varscan2
- ATG4B | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs745479816, COSV100728585; called by muse, mutect2, varscan2
- ATG9A | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs570750110, COSV100772505; called by muse, mutect2, varscan2
- ATOH8 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs760406327, COSV60399600; called by muse, mutect2, varscan2
- ATP12A | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs759125879, COSV54525072; called by muse, mutect2, varscan2
- ATP2A1 | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1446136088, COSV63921332; called by muse, mutect2
- ATP2A1 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs201798363, COSV62870624; called by muse, mutect2, varscan2
- ATP2B2 | c.3049C>T p.R1017W (on ENST00000352432; = p.R983W on NM_001683.5) | Missense Mutation (SNP) | VAF 106/271 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59502975; called by muse, mutect2, varscan2
- ATP5F1C | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.524); catalogued as rs200847831, COSV100184265; called by muse, mutect2, varscan2
- ATP6AP1 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 100/128 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs782026906, COSV62341076; called by muse, mutect2, varscan2
- ATP6V0A1 | c.797A>C p.D266A | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.559); catalogued as COSV99230537; called by muse, mutect2, varscan2
- ATP6V1H | c.1391+1G>A p.X464_splice | Splice Site (SNP) | VAF 18/71 reads (25%) | catalogued as COSV100778613; called by muse, mutect2, varscan2
- ATP8A2 | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV99680315; called by muse, mutect2, varscan2
- ATP8B4 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 109/281 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs200106056, COSV52713293; called by muse, mutect2, varscan2
- ATPSCKMT | c.650del p.R217Lfs*29 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | catalogued as COSV54727278; called by mutect2, pindel, varscan2
- ATR | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs886058056, COSV63387513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AURKA | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 94/240 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100452814; called by muse, mutect2, varscan2
- AVPR1B | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65638351; called by muse, mutect2, varscan2
- BAIAP2L2 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778728193, COSV100207064; called by muse, mutect2, varscan2
- BARD1 | c.1323A>G p.I441M | Missense Mutation (SNP) | VAF 105/320 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV99638023; called by muse, mutect2, varscan2
- BAZ1A | c.4282C>T p.R1428* | Nonsense Mutation (SNP) | VAF 25/86 reads (29%) | catalogued as COSV100701092; called by muse, mutect2, varscan2
- BBX | c.2186C>T p.P729L | Missense Mutation (SNP) | VAF 114/332 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs150437555; called by muse, mutect2, varscan2
- BCAS4 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375780908; called by muse, mutect2, varscan2
- BCL11A | c.1321G>A p.D441N (on ENST00000335712 / NM_001365609.1; = p.D475N on NM_018014.4) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs757298308, COSV59626874; called by muse, mutect2, varscan2
- BCL11A | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV100184950, COSV59625512; called by muse, mutect2, varscan2
- BCL11A | c.30G>T p.Q10H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100184961; called by muse, mutect2, varscan2
- BCL2L14 | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV99844891; called by muse, mutect2
- BCS1L | c.614T>C p.V205A | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99828851; called by muse, mutect2
- BEND3 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.073); catalogued as rs150744696; called by muse, mutect2, varscan2
- BEND5 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs201098567; called by muse, mutect2, varscan2
- BEND7 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 109/311 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100346401; called by muse, mutect2, varscan2
- BEST1 | c.636C>T p.N212= | Splice Region (SNP) | VAF 33/93 reads (35%) | catalogued as rs764196815, COSV57121311; called by muse, mutect2, varscan2
- BEST4 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.041); catalogued as COSV64734591; called by muse, mutect2, varscan2
- BICD2 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs774220760, COSV63549255; called by muse, mutect2, varscan2
- BIRC6 | c.5156T>C p.V1719A | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV101427929; called by muse, mutect2, varscan2
- BMI1 | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.406); catalogued as COSV100936316; called by muse, mutect2, varscan2
- BMS1 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs139699494; called by muse, mutect2
- BNC2 | c.2563G>A p.V855I | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as rs747700365, COSV101032323; called by muse, mutect2, varscan2
- BNC2 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 86/274 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.203); catalogued as rs753706030, COSV66156581; called by muse, mutect2, varscan2
- BOC | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV99848208; called by muse, mutect2, varscan2
- BOC | c.953A>G p.Q318R | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as COSV99848209; called by muse, mutect2, varscan2
- BOD1 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99603422; called by muse, mutect2, varscan2
- BPTF | c.7292T>C p.V2431A | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV100074232; called by muse, mutect2, varscan2
- BRD1 | c.2654C>T p.T885M (on ENST00000216267 / NM_001349940.1; = p.T1016M on NM_001304808.3) | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.931); catalogued as rs780837839, COSV53455308, COSV53460723; called by muse, mutect2, varscan2
- BRD4 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV99650003; called by muse, mutect2, varscan2
- BRPF1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs755029735, COSV57403970; called by muse, mutect2, varscan2
- BRSK1 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1182339276, COSV58670242; called by muse, varscan2
- BSN | c.3365C>T p.S1122F | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760368176, COSV99607437; called by muse, mutect2, varscan2
- BTC | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 120/380 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs782514658, COSV67547635; called by muse, mutect2, varscan2
- BUD13 | c.767T>C p.L256P | Missense Mutation (SNP) | VAF 119/344 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1295404535, COSV99496288; called by muse, mutect2, varscan2
- C11orf24 | c.1182G>T p.Q394H | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV100422499; called by muse, mutect2, varscan2
- C11orf24 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs536792763, COSV58505178, COSV58506145; called by muse, mutect2, varscan2
- C11orf54 | c.810del p.F270Lfs*18 (on ENST00000331239; = p.F220Lfs*18 on NM_014039.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 35/250 reads (14%) | catalogued as rs1243082072; called by mutect2, pindel, varscan2
- C11orf87 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as rs748774299, COSV100535686; called by muse, mutect2, varscan2
- C12orf4 | c.871C>A p.L291M | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV99712584; called by muse, mutect2, varscan2
- C17orf97 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs141704289; called by muse, mutect2, varscan2
- C1orf162 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV100636162; called by muse, mutect2, varscan2
- C2CD3 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs754367795, COSV58090296, COSV58097566; called by muse, mutect2, varscan2
- C2orf16 | c.3982G>T p.G1328* | Nonsense Mutation (SNP) | VAF 18/122 reads (15%) | catalogued as COSV62674188; called by muse, mutect2, varscan2
- C9orf135 | c.449+2T>A p.X150_splice | Splice Site (SNP) | VAF 7/43 reads (16%) | catalogued as COSV65874708, COSV65876544; called by muse, mutect2, varscan2
- CABP4 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs775087763, COSV100351440; called by muse, mutect2, varscan2
- CACNA1E | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 62/201 reads (31%) | catalogued as COSV62393616; called by muse, mutect2, varscan2
- CACNA1E | c.5332G>A p.G1778S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1301005373, COSV62388135; called by muse, mutect2, varscan2
- CACNA1G | c.4664G>A p.R1555Q | Missense Mutation (SNP) | VAF 224/589 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61721208; called by muse, mutect2, varscan2
- CACNA1G | c.5095G>A p.A1699T | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV61721223; called by muse, mutect2, varscan2
- CACNA1H | c.5629G>A p.D1877N | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99326414; called by muse, mutect2, varscan2
- CACNA1S | c.5248A>G p.M1750V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs771065920, COSV100754707; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1S | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs373218444; called by muse, mutect2, varscan2
- CACNA2D3 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.85); catalogued as rs764440125, COSV55512686; called by muse, mutect2, varscan2
- CACNA2D4 | c.2090G>A p.R697Q | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs577055633, COSV54946200; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACTIN | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs762886918, COSV99698320; called by muse, mutect2, varscan2
- CACTIN | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99698324; called by muse, mutect2, varscan2
- CADPS2 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.857); catalogued as rs756409034, COSV100460109; called by muse, mutect2, varscan2
- CAMK4 | c.803A>G p.E268G | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV99998459; called by muse, mutect2, varscan2
- CAMSAP1 | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100409622; called by muse, varscan2
- CAMTA2 | c.2497G>T p.D833Y | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99236224; called by muse, mutect2, varscan2
- CAP2 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV100012160; called by muse, mutect2, varscan2
- CAPN1 | c.1211C>T p.T404M | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs769161725, COSV54202829; called by muse, mutect2, varscan2
- CAPN10 | c.451C>A p.L151M | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99549994; called by muse, mutect2, varscan2
- CAPN10 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.849); catalogued as rs372639976; called by muse, mutect2, varscan2
- CAPN7 | c.2024G>A p.C675Y | Missense Mutation (SNP) | VAF 115/389 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs755588973, COSV99512588; called by muse, mutect2, varscan2
- CAPSL | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV68437377; called by muse, mutect2
- CAPZA1 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV99582917; called by muse, mutect2, varscan2
- CAPZA2 | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV100753837; called by muse, mutect2
- CARD11 | c.2336G>A p.R779Q | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1184296576, COSV100829092; called by muse, mutect2, varscan2
- CARM1 | c.1430C>T p.T477M | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs1263062756, COSV99449863; called by muse, mutect2, varscan2
- CARMIL3 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as rs750682495, COSV100549302; called by muse, mutect2, varscan2
- CARS1 | c.1181T>G p.F394C | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99542105; called by muse, mutect2, varscan2
- CASP2 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs756201685, COSV60083903; called by muse, mutect2, varscan2
- CASP8 | c.1294C>T p.R432* (on ENST00000432109 / NM_033355.3; = p.R449* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as rs931648756, COSV51845077; called by muse, mutect2, varscan2
- CASP8AP2 | c.1823C>T p.S608F | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV99386795; called by muse, mutect2, varscan2
- CASP8AP2 | c.5650G>A p.A1884T | Missense Mutation (SNP) | VAF 168/433 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV99386797; called by muse, mutect2, varscan2
- CATSPERD | c.1901T>C p.M634T | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs1040147078, COSV100486677; called by muse, mutect2, varscan2
- CAVIN1 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.214); catalogued as rs1252853553, COSV63811558; called by muse, mutect2, varscan2
- CBFA2T3 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1259395071, COSV99241178; called by muse, mutect2
- CBX6 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99327983; called by muse, mutect2
- CC2D1B | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs140457418; called by muse, mutect2, varscan2
- CCBE1 | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs1440722176, COSV101232778; called by muse, mutect2, varscan2
- CCDC102B | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs369503833; called by muse, mutect2, varscan2
- CCDC130 | c.4G>T p.G2C | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99681139; called by muse, mutect2, varscan2
- CCDC141 | c.3818C>T p.A1273V | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs770849745, COSV55370128; called by muse, mutect2, varscan2
- CCDC158 | c.3023C>T p.A1008V | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs1278994856, COSV101187165; called by muse, mutect2, varscan2
- CCDC170 | c.1728G>T p.Q576H | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99498171; called by muse, mutect2, varscan2
- CCDC186 | c.298A>G p.N100D | Missense Mutation (SNP) | VAF 212/511 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100990990; called by muse, mutect2, varscan2
- CCDC60 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs775527936, COSV59539642; called by muse, mutect2, varscan2
- CCDC60 | c.1161G>T p.R387S | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100554684, COSV59543517; called by muse, mutect2, varscan2
- CCDC87 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV100039776; called by muse, mutect2, varscan2
- CCDC88B | c.2936G>A p.R979Q | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs566542432, COSV57265614; called by muse, mutect2, varscan2
- CCDC88C | c.2062G>A p.V688M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as rs375082540; called by muse, mutect2, varscan2
- CCM2 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 95/309 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs750771937, COSV51847292; called by muse, mutect2, varscan2
- CCN1 | c.892T>C p.F298L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV101486115; called by muse, mutect2, varscan2
- CCNC | c.268T>C p.C90R | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV100412539; called by muse, mutect2, varscan2
- CCNT1 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 98/284 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV99980509; called by muse, mutect2, varscan2
- CCP110 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs781615627, COSV66816671; called by muse, mutect2, varscan2
- CCR1 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as rs1419201949, COSV99946653; called by muse, mutect2, varscan2
- CCT3 | c.1567G>A p.V523I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.546); catalogued as rs373870763; called by muse, mutect2, varscan2
- CD244 | c.493G>A p.V165M (on ENST00000368033 / NM_001166663.2; = p.V160M on NM_016382.4) | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1557835480, COSV100458287; called by muse, mutect2, varscan2
- CD2AP | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100830579; called by muse, mutect2
- CD300LF | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as rs1355258308, COSV56899334; called by muse, mutect2, varscan2
- CD5 | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100759760; called by muse, mutect2, varscan2
- CD70 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs182050995, COSV55565917; called by muse, mutect2, varscan2
- CD79A | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as rs953006206, COSV99701933; called by muse, varscan2
- CDC27 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 126/358 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV50364249; called by muse, mutect2, varscan2
- CDC27 | c.2288C>T p.A763V | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50367411; called by muse, mutect2, varscan2
- CDC42BPA | c.3251C>T p.A1084V (on ENST00000334218 / NM_001366019.2; = p.A1071V on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV62004266; called by muse, mutect2, varscan2
- CDCA3 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs148172476; called by muse, mutect2, varscan2
- CDH10 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.377); catalogued as rs149518689, COSV52582534; called by muse, mutect2, varscan2
- CDH12 | c.1257-2A>G p.X419_splice | Splice Site (SNP) | VAF 67/186 reads (36%) | catalogued as COSV101201703; called by muse, mutect2, varscan2
- CDH2 | c.1703A>G p.N568S | Missense Mutation (SNP) | VAF 126/336 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99295882; called by muse, mutect2, varscan2
- CDH23 | c.8674C>T p.R2892W | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs1468886300, COSV56482903, COSV99819181; called by muse, mutect2, varscan2
- CDH4 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as rs1201669774, COSV64648959; called by muse, mutect2, varscan2
- CDH6 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs1230259081, COSV54065620; called by muse, mutect2, varscan2
- CDH8 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); catalogued as rs548909736, COSV100179850; called by muse, mutect2, varscan2
- CDH9 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as rs368164243; called by muse, mutect2, varscan2
- CDHR5 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 84/179 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs764162002, COSV99449117; called by muse, mutect2, varscan2
- CDK12 | c.4266G>T p.K1422N (on ENST00000447079 / NM_016507.4; = p.K1413N on NM_015083.3) | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.382); catalogued as COSV101420377; called by muse, mutect2, varscan2
- CDK19 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100098084; called by muse, mutect2, varscan2
- CDK2 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV57186695, COSV99906668; called by muse, mutect2, varscan2
- CDK5R1 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV55580382; called by muse, varscan2
- CDON | c.597T>G p.H199Q | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV99700714; called by muse, mutect2, varscan2
- CDRT15 | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101415138; called by muse, mutect2, varscan2
- CDYL | c.1161C>A p.S387R (on ENST00000328908 / NM_001368125.1; = p.S333R on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100188825; called by muse, mutect2, varscan2
- CELF3 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1198353062, COSV51886111; called by muse, mutect2, varscan2
- CELSR3 | c.4740G>A p.T1580= | Splice Region (SNP) | VAF 24/154 reads (16%) | catalogued as rs200430426, COSV51145625; called by muse, mutect2, varscan2
- CENPA | c.258G>A p.W86* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as COSV99273131; called by muse, mutect2, varscan2
- CEP126 | c.2888G>A p.R963Q | Missense Mutation (SNP) | VAF 93/225 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs150274963; called by muse, mutect2, varscan2
- CEP170B | c.4346G>A p.R1449H (on ENST00000453495; = p.R1378H on NM_015005.3) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1326315392, COSV99229694; called by muse, varscan2
- CERKL | c.986T>G p.L329R (on ENST00000339098 / NM_001030311.2; = p.L303R on NM_201548.5) | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100183216; called by muse, mutect2, varscan2
- CERT1 | c.1741G>A p.V581I (on ENST00000405807 / NM_001130105.1; = p.V453I on NM_005713.3) | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as COSV54659813; called by muse, mutect2, varscan2
- CES2 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs761698722, COSV57697447; called by muse, mutect2, varscan2
- CETN1 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs775173037, COSV59121801; called by muse, mutect2, varscan2
- CETN1 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs775593048, COSV59120994; called by muse, mutect2, varscan2
- CFAP221 | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 49/127 reads (39%) | catalogued as rs760469971, COSV54657957; called by muse, mutect2, varscan2
- CFAP43 | c.4810A>G p.K1604E | Missense Mutation (SNP) | VAF 133/350 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as COSV100829082; called by muse, mutect2, varscan2
- CFAP52 | c.1775G>A p.R592H | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs566597331, COSV99556422; called by muse, mutect2, varscan2
- CFAP61 | c.2848C>A p.L950I | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99843532; called by muse, mutect2, varscan2
- CFAP70 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs777001340, COSV100160225; called by muse, mutect2, varscan2
- CGAS | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs531954415, COSV100943643, COSV64808063; called by muse, mutect2, varscan2
- CHAF1A | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775109223, COSV56671455; called by muse, mutect2, varscan2
- CHCHD5 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV61424261; called by muse, mutect2
- CHD1 | c.3358C>T p.R1120W | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs768739262, COSV52344696; called by muse, mutect2, varscan2
- CHD2 | c.3346C>T p.R1116C | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs200013427, COSV99064025; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD3 | c.2377C>A p.P793T | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100390790; called by muse, mutect2, varscan2
- CHD5 | c.4336G>A p.A1446T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV99312650; called by muse, mutect2, varscan2
- CHD6 | c.6565G>A p.A2189T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as rs1471950922, COSV100950608; called by muse, mutect2
- CHD6 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 90/266 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.166); catalogued as rs759903834, COSV58560819; called by muse, mutect2, varscan2
- CHD9 | c.4631G>A p.R1544Q | Missense Mutation (SNP) | VAF 116/305 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1212023003, COSV99528775; called by muse, mutect2, varscan2
- CHD9 | c.6166C>A p.P2056T | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV99528777; called by muse, mutect2, varscan2
- CHID1 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.924); catalogued as rs745451507, COSV60260212; called by muse, mutect2, varscan2
- CHRM3 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55110356, COSV99697656; called by muse, mutect2, varscan2
- CHRND | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.046); catalogued as COSV99285552; called by muse, mutect2, varscan2
- CHRNE | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV99544599; called by muse, mutect2, varscan2
- CHST1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV57323162; called by muse, mutect2, varscan2
- CHST1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.065); catalogued as rs763733732, COSV57321916, COSV57325297; called by muse, mutect2, varscan2
- CHST1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 145/405 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs140694718; called by muse, mutect2, varscan2
- CHST11 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57984409; called by muse, mutect2, varscan2
- CHST12 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.485); catalogued as rs1430278569, COSV99324329; called by muse, mutect2, varscan2
- CIAO3 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV52401084; called by muse, mutect2, varscan2
- CIBAR2 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774262113, COSV73320627; called by muse, varscan2
- CIBAR2 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs140432540; called by muse, varscan2
- CIITA | c.3124C>T p.L1042F | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60854773; called by muse, mutect2, varscan2
- CKMT1B | c.1175A>G p.Y392C | Missense Mutation (SNP) | VAF 140/366 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV100294449; called by muse, mutect2, varscan2
- CLASP1 | c.2302C>T p.R768W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs765905351, COSV55315928; called by muse, mutect2, varscan2
- CLCA4 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 128/324 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as rs751030317, COSV55367258; called by muse, mutect2, varscan2
- CLEC4F | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs546185298, COSV55478455; called by muse, mutect2
- CLHC1 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV100811470; called by muse, mutect2, varscan2
- CLIP1 | c.4246C>T p.R1416C (on ENST00000620786 / NM_001247997.1; = p.R1405C on NM_002956.2) | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs999756920, COSV100211294; called by muse, mutect2, varscan2
- CLIP3 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); catalogued as COSV62111818; called by muse, mutect2, varscan2
- CLOCK | c.2261C>T p.T754M | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.451); catalogued as rs538817792, COSV100011621; called by muse, varscan2
- CLSTN3 | c.2773G>A p.G925S | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs974252851, COSV99866602; called by muse, mutect2, varscan2
- CLUH | c.3715G>A p.V1239I (on ENST00000435359; = p.V1278I on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs958704192, COSV101425641; called by muse, mutect2, varscan2
- CLUH | c.2791C>T p.R931W (on ENST00000435359; = p.R970W on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429903193, COSV70929442; called by muse, mutect2, varscan2
- CLVS1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs781486942, COSV57970316; called by muse, mutect2, varscan2
- CLVS2 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761889566, COSV51570371; called by muse, mutect2, varscan2
- CNGA4 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV66005788; called by muse, mutect2, varscan2
- CNGB1 | c.3154A>G p.T1052A | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs751034406, COSV99201650; called by muse, mutect2, varscan2
- CNGB1 | c.2293C>A p.R765S | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM1310196, COSV99201656; called by muse, mutect2
- CNNM1 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs1181296195, COSV100763774; called by muse, varscan2
- CNNM1 | c.1762C>T p.R588W | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs1421751680, COSV63200658; called by muse, mutect2
- CNNM2 | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 99/261 reads (38%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.691); catalogued as COSV100881815; called by muse, mutect2, varscan2
- CNOT1 | c.6617C>A p.P2206H | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99799362; called by muse, mutect2, varscan2
- CNOT1 | c.4186G>A p.A1396T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs1202901051, COSV55313915; called by muse, mutect2, varscan2
- CNTN6 | c.958T>A p.W320R | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100610169; called by muse, mutect2, varscan2
- CNTNAP4 | c.3308T>C p.L1103P | Missense Mutation (SNP) | VAF 69/268 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV56668306; called by muse, mutect2, varscan2
- CNTROB | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207138758, COSV58050555; called by muse, mutect2, varscan2
- COBL | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771778534, COSV54358837; called by muse, mutect2, varscan2
- COG1 | c.1594C>A p.L532I | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.446); catalogued as COSV100245155; called by muse, mutect2, varscan2
- COG7 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs745329738, COSV100207390; called by muse, mutect2, varscan2
- COL17A1 | c.3182C>T p.A1061V | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100793070; called by muse, mutect2, varscan2
- COL1A2 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs550867796, COSV51953044; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL1A2 | c.2905G>A p.V969M | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs765448220, COSV51955294; called by muse, mutect2, varscan2
- COL23A1 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 146/444 reads (33%) | catalogued as rs373614230; called by muse, varscan2
- COL2A1 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV61532230; called by muse, mutect2, varscan2
- COL4A1 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65427226; called by muse, mutect2, varscan2
- COL4A4 | c.2896G>A p.A966T | Missense Mutation (SNP) | VAF 71/222 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV100306331; called by muse, mutect2, varscan2
- COL4A5 | c.4270G>T p.G1424* | Nonsense Mutation (SNP) | VAF 115/169 reads (68%) | catalogued as COSV100086705; called by muse, mutect2, varscan2
- COL5A1 | c.5206G>A p.A1736T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as rs753339980, COSV100879601, COSV65672401; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL6A6 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0.164); catalogued as COSV62022033; called by muse, mutect2, varscan2
- COPB1 | c.2120A>G p.D707G | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV99999291; called by muse, mutect2, varscan2
- CORIN | c.1650G>T p.Q550H | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56691609; called by muse, mutect2
- CORO2B | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs946241969, COSV99962949; called by muse, mutect2, varscan2
- COX4I2 | c.23G>A p.S8N | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV101064189; called by muse, mutect2, varscan2
- COX4I2 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568834783, COSV65781795; called by muse, mutect2, varscan2
- CPAMD8 | c.2684A>G p.Q895R (on ENST00000651564; = p.Q848R on NM_015692.5) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV101488420; called by muse, mutect2, varscan2
- CPEB1 | c.1832G>A p.R611H (on ENST00000617958; = p.R546H on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.535); catalogued as rs1242647902; called by muse, mutect2, varscan2
- CPNE2 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.631); catalogued as rs748317019, COSV99321273; called by muse, mutect2, varscan2
- CRACD | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs1489054487, COSV51724263; called by muse, mutect2, varscan2
- CRACD | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1391582872, COSV99948703; called by muse, mutect2, varscan2
- CRACR2B | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as rs750751434, COSV58989356; called by muse, mutect2, varscan2
- CREB3L1 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1378914897, COSV99914847; called by muse, mutect2, varscan2
- CREB3L1 | c.1225C>A p.L409M | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99914849; called by muse, mutect2, varscan2
- CREBBP | c.5048G>A p.R1683H | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1247401109, COSV52129686, COSV99268787; called by muse, mutect2, varscan2
- CREM | c.782C>T p.A261V (on ENST00000429130; = p.A216V on NM_181571.3) | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV59765613; called by muse, mutect2, varscan2
- CRIM1 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs560635455, COSV99752611; called by muse, mutect2, varscan2
- CRIM1 | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs145410862; called by muse, varscan2
- CRISPLD2 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1280091250, COSV52280583, COSV99295429; called by muse, mutect2, varscan2
- CRNKL1 | c.1482G>A p.W494* | Nonsense Mutation (SNP) | VAF 35/89 reads (39%) | catalogued as COSV101056878; called by muse, mutect2, varscan2
- CRYBB3 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as rs1028096414, COSV99308990; called by muse, varscan2
- CSE1L | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 144/407 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.188); catalogued as rs149344844; called by muse, mutect2, varscan2
- CSF3R | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 136/334 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs375879178; called by muse, mutect2, varscan2
- CSMD1 | c.7253C>T p.A2418V (on ENST00000520002; = p.A2417V on NM_033225.6) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV100144566; called by muse, mutect2
- CSMD1 | c.2690C>T p.T897I (on ENST00000520002; = p.T896I on NM_033225.6) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100144568, COSV59383150; called by muse, mutect2, varscan2
- CSMD2 | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.498); catalogued as rs777884398, COSV53885258; called by muse, mutect2, varscan2
- CSNK1A1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 99/305 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as COSV55798158; called by muse, mutect2, varscan2
- CSNK1D | c.479G>C p.R160P | Missense Mutation (SNP) | VAF 150/429 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV53923252, COSV53927606; called by muse, mutect2, varscan2
- CSNK2A1 | c.1154C>A p.A385D | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as COSV99424223; called by muse, mutect2
- CSPG5 | c.1196G>A p.C399Y | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99273658; called by muse, varscan2
- CST8 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs372735686, COSV55671015; called by muse, mutect2, varscan2
- CT83 | c.263A>G p.E88G | Missense Mutation (SNP) | VAF 112/151 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100902519; called by muse, mutect2, varscan2
- CTNNA1 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs1211833493, COSV100242237; called by muse, mutect2
- CTNNA1 | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1274345685, COSV57070748, COSV57077454; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA2 | c.2005C>T p.R669W | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58134821; called by muse, mutect2, varscan2
- CTNNA3 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 60/198 reads (30%) | catalogued as rs771161312, COSV65609273; called by muse, mutect2, varscan2
- CTR9 | c.3365G>A p.R1122H | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.067); catalogued as rs367908001, COSV63729129; called by muse, mutect2, varscan2
- CUBN | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.701); catalogued as rs747836605, COSV100912153; called by muse, mutect2
- CWF19L1 | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs746097669, COSV62499451; called by muse, mutect2, varscan2
- CWF19L1 | c.196C>G p.Q66E | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as COSV100821465, COSV62499703; called by muse, mutect2, varscan2
- CYFIP1 | c.3328C>T p.R1110C | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.791); catalogued as rs1403318284, COSV100487837; called by muse, mutect2, varscan2
- CYFIP2 | c.2455A>G p.I819V (on ENST00000616178 / NM_001291722.2; = p.I794V on NM_014376.4) | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV59030076; called by muse, mutect2, varscan2
- CYP17A1 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV64004881; called by muse, varscan2
- CYP1A1 | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101122228; called by muse, mutect2, varscan2
- CYP20A1 | c.851-2A>G p.X284_splice | Splice Site (SNP) | VAF 35/178 reads (20%) | catalogued as rs776103317, COSV61909148; called by muse, mutect2, varscan2
- CYP2A7 | c.1159A>G p.K387E | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV99393738; called by muse, mutect2, varscan2
- CYP2A7 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 175/472 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs147586806; called by muse, mutect2, varscan2
- CYP3A7 | c.522C>T p.H174= | Splice Region (SNP) | VAF 90/260 reads (35%) | catalogued as rs752032213, COSV100312572, COSV60481746; called by muse, mutect2, varscan2
- CYP4A11 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs556756716, COSV60224205; called by muse, mutect2, varscan2
- CYP4F2 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as COSV50001360, COSV99171039; called by muse, mutect2, varscan2
- CYP4Z1 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 120/365 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV100497537; called by muse, varscan2
- DAAM2 | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.683); catalogued as rs192352327; called by muse, mutect2, varscan2
- DAAM2 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776017051, COSV99224789; called by muse, mutect2, varscan2
- DAB2IP | c.1768C>T p.R590C (on ENST00000408936; = p.R562C on NM_032552.3) | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.68); catalogued as rs766959002, COSV52257062; called by muse, mutect2, varscan2
- DARS1 | c.238C>A p.L80I | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV99927356; called by muse, mutect2, varscan2
- DCLK1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55214935; called by muse, mutect2, varscan2
- DCLK3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 86/195 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV69363914; called by muse, mutect2, varscan2
- DCP2 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369278042; called by muse, mutect2, varscan2
- DCPS | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs773359297, COSV55010758; called by muse, mutect2, varscan2
- DDI1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs766051930, COSV56384748; called by muse, mutect2, varscan2
- DDR1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs981246535, COSV61319742; called by muse, mutect2, varscan2
- DDX47 | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV100774499; called by muse, mutect2, varscan2
- DDX55 | c.842A>T p.E281V | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV99434237; called by muse, mutect2, varscan2
- DDX58 | c.141_143del p.N47del | In Frame Del (DEL) | VAF 22/90 reads (24%) | catalogued as rs750396858; called by pindel, varscan2
- DEFB135 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as COSV101198535; called by muse, mutect2, varscan2
- DENND2B | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1429393379, COSV58204077; called by muse, mutect2, varscan2
- DENND2B | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs537720382, COSV100567186; called by muse, varscan2
- DENND2B | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs577617101, COSV100567187; called by muse, varscan2
- DENND4A | c.3605G>A p.R1202H | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs912976987, COSV71265469; called by muse, mutect2, varscan2
- DENND4B | c.2350C>T p.R784W | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1243030311, COSV63409691; called by muse, mutect2, varscan2
- DENND5A | c.3638G>A p.G1213D | Missense Mutation (SNP) | VAF 57/311 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60232818, COSV60234314; called by muse, mutect2, varscan2
- DENND5A | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs965362811, COSV60238382; called by muse, mutect2, varscan2
- DENND6A | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs748884235, COSV100231295; called by muse, mutect2, varscan2
- DES | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs374687448; called by muse, mutect2, varscan2
- DGCR2 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs138741169; called by muse, mutect2, varscan2
- DGKD | c.1456G>A p.A486T (on ENST00000264057 / NM_152879.3; = p.A442T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0.009); catalogued as COSV99895545; called by muse, mutect2, varscan2
- DGKD | c.3358G>A p.V1120M (on ENST00000264057 / NM_152879.3; = p.V1076M on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.927); catalogued as rs1043520472, COSV51034551; called by muse, mutect2, varscan2
- DGKK | c.3110G>A p.R1037Q | Missense Mutation (SNP) | VAF 67/96 reads (70%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs782556247, COSV101052899; called by muse, mutect2, varscan2
- DHODH | c.190C>A p.L64M | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV99536767; called by muse, mutect2, varscan2
- DHRS3 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201342762, COSV66108426; called by muse, mutect2, varscan2
- DHRS9 | c.425T>C p.I142T | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV100513342; called by muse, mutect2, varscan2
- DHX30 | c.2267G>A p.R756H (on ENST00000445061 / NM_138615.3; = p.R717H on NM_014966.3) | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV99274794; called by muse, mutect2, varscan2
- DHX35 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 101/233 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs138301896; called by muse, mutect2, varscan2
- DHX37 | c.691G>T p.A231S | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100439030; called by muse, mutect2
- DHX40 | c.2315G>A p.S772N | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.055); catalogued as COSV99232763; called by muse, mutect2, varscan2
- DHX57 | c.2195del p.L732Wfs*7 | Frame Shift Del (DEL) | VAF 74/205 reads (36%) | catalogued as rs749610132; called by mutect2, varscan2
- DHX57 | c.2021C>T p.T674I | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99769139; called by muse, mutect2, varscan2
- DHX9 | c.967C>T p.R323* | Nonsense Mutation (SNP) | VAF 52/131 reads (40%) | catalogued as COSV100841260; called by muse, mutect2, varscan2
- DIO3 | c.110G>T p.R37M | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100832052; called by muse, mutect2, varscan2
- DIP2C | c.4265G>A p.R1422Q | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs373727129; called by muse, mutect2, varscan2
- DLK1 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1186718844, COSV100375015; called by muse, mutect2, varscan2
- DMGDH | c.786A>C p.E262D | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV99668536; called by muse, mutect2
- DMXL1 | c.6866C>T p.T2289M | Missense Mutation (SNP) | VAF 84/449 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs766247765, COSV60712432; called by muse, mutect2, varscan2
- DMXL2 | c.1517C>A p.P506H | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99196002; called by muse, mutect2, varscan2
- DMXL2 | c.326dup p.L109Ffs*15 | Frame Shift Ins (INS) | VAF 42/148 reads (28%) | catalogued as rs752363479; called by mutect2, varscan2
- DNAH11 | c.4230G>A p.W1410* | Nonsense Mutation (SNP) | VAF 47/128 reads (37%) | catalogued as rs367916239, COSV100177549; called by muse, varscan2
- DNAH17 | c.6475C>T p.P2159S | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67750577, COSV67751969; called by muse, mutect2, varscan2
- DNAH5 | c.12212G>A p.R4071H | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs745403938, COSV54251714; called by muse, mutect2, varscan2
- DNAH5 | c.3907C>T p.H1303Y | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99445713; called by muse, mutect2, varscan2
- DNAH8 | c.9095G>A p.R3032H | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1386224345, COSV100543536; called by muse, mutect2, varscan2
- DNAH8 | c.10040G>A p.R3347Q | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.49); catalogued as rs772835642, COSV100543539; called by muse, mutect2, varscan2
- DNAI2 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1228330378, COSV56756534; called by muse, mutect2, varscan2
- DNAJC13 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as rs1475034512, COSV53453556; called by muse, mutect2, varscan2
- DNM1 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57854019; called by muse, mutect2, varscan2
- DNM2 | c.2170C>T p.R724C (on ENST00000355667 / NM_001005360.3; = p.R720C on NM_004945.3) | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs749953105, COSV99284042; called by muse, mutect2, varscan2
- DNTTIP1 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs1480105771, COSV99714423; called by muse, mutect2, varscan2
- DOCK11 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 132/192 reads (69%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.474); catalogued as COSV99353047; called by muse, mutect2, varscan2
- DOCK2 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV56938995; called by muse, mutect2, varscan2
- DOCK5 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs757595575, COSV99376193; called by muse, mutect2, varscan2
- DOCK6 | c.2867G>A p.R956H | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772731799, COSV99624902; called by muse, mutect2
- DOCK6 | c.2522G>A p.R841H | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs372044294, COSV52949032; called by muse, mutect2, varscan2
- DOCK6 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1162772773, COSV52949801; called by muse, mutect2, varscan2
- DOCK8 | c.3339dup p.M1114Yfs*4 | Frame Shift Ins (INS) | VAF 70/186 reads (38%) | catalogued as rs748134881; called by mutect2, varscan2
- DOLK | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs377658203, COSV100454971; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOP1A | c.6847A>G p.N2283D | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99381101; called by muse, mutect2, varscan2
- DPEP1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 56/160 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1428413464, COSV99878327; called by muse, mutect2, varscan2
- DPP10 | c.668T>C p.F223S | Missense Mutation (SNP) | VAF 93/251 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV59669349, COSV59678423; called by muse, mutect2, varscan2
- DPP10 | c.1951-1G>T p.X651_splice | Splice Site (SNP) | VAF 36/66 reads (55%) | catalogued as COSV59669368; called by muse, varscan2
- DPP8 | c.493G>A p.G165R (on ENST00000341861 / NM_001320875.2; = p.G149R on NM_017743.6) | Missense Mutation (SNP) | VAF 98/304 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as rs1432951432, COSV55681000; called by muse, mutect2, varscan2
- DPYS | c.632T>C p.I211T | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV100679302; called by muse, mutect2, varscan2
- DPYSL4 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1229373997, COSV100633846, COSV104406378; called by muse, varscan2
- DRAXIN | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs758315246, COSV53843821; called by muse, mutect2, varscan2
- DRC1 | c.630G>T p.Q210H | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV99985079; called by muse, mutect2, varscan2
- DRC1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 85/208 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs756180718, COSV56536506; called by muse, mutect2, varscan2
- DRG1 | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100513610; called by muse, varscan2
- DROSHA | c.2240C>T p.T747M | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs202101007; called by muse, mutect2, varscan2
- DSC1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs759805213, COSV99937279; called by muse, mutect2, varscan2
- DSCAML1 | c.2323G>A p.G775S (on ENST00000321322; = p.G715S on NM_020693.4) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as rs1565746977, COSV100354832; called by muse, mutect2, varscan2
- DSG2 | c.2212G>A p.A738T | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs397516705, COSV99852584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSG4 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.362); catalogued as rs200219673, COSV57392942; called by muse, mutect2
- DSG4 | c.2410C>G p.L804V | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100355414; called by muse, mutect2, varscan2
- DST | c.10474G>A p.V3492M | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs754875119, COSV99751778, COSV99758395; called by muse, mutect2, varscan2
- DSTN | c.308del p.L103Cfs*6 | Frame Shift Del (DEL) | VAF 40/258 reads (16%) | catalogued as rs750962255; called by mutect2, varscan2
- DTNA | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764410940, COSV51993542; called by muse, mutect2, varscan2
- DUOX1 | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs763581105, COSV58485311; called by muse, mutect2, varscan2
- DUOXA1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99972883; called by muse, mutect2, varscan2
- DUSP4 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375453930; called by muse, mutect2, varscan2
- DYNC1H1 | c.3286G>A p.A1096T | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV100794533; called by muse, mutect2, varscan2
- DYSF | c.2876G>A p.R959Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs752689148, COSV99244762; called by muse, mutect2, varscan2
- EAF1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 102/240 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs145558221; called by muse, mutect2, varscan2
- EBF3 | c.1496C>T p.A499V (on ENST00000355311 / NM_001375392.1; = p.A490V on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.097); catalogued as COSV62472611; called by muse, varscan2
- EBF3 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1162714375, COSV62472617; called by muse, mutect2, varscan2
- EDEM1 | c.791C>G p.A264G | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99849035; called by muse, mutect2, varscan2
- EDEM3 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100544943; called by muse, mutect2, varscan2
- EDNRB | c.518G>A p.R173H (on ENST00000377211 / NM_001201397.1; = p.R83H on NM_000115.5) | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV57518783; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.681); catalogued as COSV62566987; called by muse, mutect2, varscan2
- EFCAB12 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs149643945, COSV100394494; called by muse, mutect2, varscan2
- EFCAB5 | c.917A>C p.K306T | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100299848; called by muse, mutect2, varscan2
- EFHB | c.2207G>A p.R736H | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs770766960, COSV55545385; called by muse, mutect2, varscan2
- EFNB1 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 100/121 reads (83%) | SIFT tolerated (0.46); PolyPhen benign (0.024); catalogued as rs767055938, COSV99214746; called by muse, mutect2, varscan2
- EFTUD2 | c.2816G>A p.R939H | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763935473, COSV99493825; called by muse, mutect2, varscan2
- EGR2 | c.320G>A p.C107Y | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.157); catalogued as COSV54348637; called by muse, mutect2, varscan2
- EHBP1 | c.2581C>T p.R861* | Nonsense Mutation (SNP) | VAF 26/66 reads (39%) | catalogued as rs564779105, COSV50415500, COSV50415523; called by muse, mutect2, varscan2
- EHBP1L1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764167148, COSV57079108; called by muse, mutect2, varscan2
- EHD2 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV99621686; called by muse, mutect2, varscan2
- EHD3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as COSV100434603, COSV100434868; called by muse, mutect2, varscan2
- EHF | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.997); catalogued as rs1047253844, COSV57669855; called by muse, mutect2, varscan2
- EID3 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377416878, COSV100723321; called by muse, mutect2, varscan2
- EIF2AK4 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55469009; called by muse, mutect2, varscan2
- EIF2AK4 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.798); catalogued as COSV99774156; called by muse, mutect2, varscan2
- EIF3E | c.1229G>A p.S410N | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV99622841; called by muse, mutect2, varscan2
- EIF4A3 | c.168C>T p.Y56= | Splice Region (SNP) | VAF 4/12 reads (33%) | catalogued as COSV53919796; called by muse, mutect2
- EIF4ENIF1 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs774326417, COSV100348893; called by muse, mutect2, varscan2
- EIF5B | c.1589A>C p.N530T | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV99176848; called by muse, mutect2
- ELF5 | c.377G>A p.R126H (on ENST00000312319 / NM_198381.2; = p.R116H on NM_001422.4) | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs371514980, COSV56628705; called by muse, mutect2, varscan2
- ELMO2 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs776816963, COSV51684095; called by muse, mutect2, varscan2
- ELMO3 | c.1238G>A p.R413H (on ENST00000652269; = p.R360H on NM_024712.5) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as rs765459031, COSV100681454; called by muse, mutect2, varscan2
- ELMOD1 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 113/298 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.069); catalogued as rs369345306; called by muse, varscan2
- ELN | c.1957+2T>C p.X653_splice (on ENST00000320399 / NM_001278939.1; = p.X620_splice on NM_000501.4) | Splice Site (SNP) | VAF 44/112 reads (39%) | catalogued as rs1554686159, COSV99332337; called by muse, varscan2
- ENAM | c.2242G>A p.V748I | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs756300242, COSV101252934; called by muse, mutect2, varscan2
- ENC1 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 18/294 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100187933; called by muse, mutect2
- ENO3 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.826); catalogued as rs755474025, COSV99236223; called by muse, mutect2, varscan2
- ENTPD3 | c.1427C>A p.P476H | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV100088485; called by muse, mutect2, varscan2
- ENTPD7 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.769); catalogued as rs769580214, COSV100978323, COSV65112141; called by muse, mutect2, varscan2
- EP300 | c.4886C>T p.A1629V | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54330195; called by muse, mutect2, varscan2
- EP400 | c.8653G>A p.V2885I | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs777299510, COSV57781701; called by muse, mutect2, varscan2
- EPAS1 | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766854881, COSV99762957; called by muse, mutect2, varscan2
- EPG5 | c.2903C>T p.A968V | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV99956601; called by muse, mutect2, varscan2
- EPHA5 | c.1778T>C p.L593P | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV99896690; called by muse, mutect2, varscan2
- EPHB1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.569); catalogued as COSV101212746; called by muse, mutect2, varscan2
- EPHB2 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs777940741, COSV65859776; called by muse, mutect2, varscan2
- EPHB6 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201326184, COSV67417398; called by muse, varscan2
- EPHB6 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV101235946; called by muse, mutect2, varscan2
- EPN3 | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs539835428, COSV99276738; called by muse, mutect2, varscan2
- EPS15 | c.1609G>T p.A537S | Missense Mutation (SNP) | VAF 129/321 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.11); catalogued as COSV100869427; called by muse, mutect2, varscan2
- EPS8L1 | c.868C>T p.R290C (on ENST00000201647 / NM_133180.3; = p.R163C on NM_017729.3) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV52380386; called by muse, mutect2, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 80/227 reads (35%) | catalogued as rs768793415; called by mutect2, varscan2
- ERBB2 | c.788T>C p.I263T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54064914; called by muse, mutect2, varscan2
- ERBB2 | c.1316G>A p.G439D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99506910; called by muse, mutect2, varscan2
- ERBB4 | c.1294C>A p.L432M | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.88); catalogued as COSV99617538; called by muse, mutect2, varscan2
- ERBIN | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs776446365, COSV52319531; called by muse, mutect2, varscan2
- ERG | c.1232del p.P411Rfs*25 (on ENST00000398919 / NM_001243428.1; = p.P387Rfs*25 on NM_004449.4) | Frame Shift Del (DEL) | VAF 55/174 reads (32%) | catalogued as COSV55735041; called by mutect2, pindel, varscan2
- ERG | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.271); catalogued as rs146705250; called by muse, mutect2, varscan2
- ERICH3 | c.2485dup p.R829Kfs*25 | Frame Shift Ins (INS) | VAF 38/159 reads (24%) | catalogued as rs35151101; called by mutect2, pindel, varscan2
- ERICH6 | c.1727A>C p.K576T | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.183); catalogued as COSV99901402; called by muse, mutect2, varscan2
- ESPL1 | c.5440G>T p.G1814C | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV54475301, COSV99228961; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 68/188 reads (36%) | catalogued as rs775950025; called by mutect2, varscan2
- ESYT1 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1469731948, COSV57273057; called by muse, mutect2, varscan2
- EVC | c.1444G>T p.D482Y | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV99381243; called by muse, mutect2, varscan2
- EXOC3 | c.2164G>A p.A722T | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100155135; called by muse, mutect2
- EXOC4 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs775034999, COSV54089612; called by muse, mutect2, varscan2
- EXOC6 | c.424T>A p.Y142N | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV99591530; called by muse, mutect2, varscan2
- EXOSC2 | c.58C>A p.R20S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs140638723, COSV100964234; called by muse, mutect2, varscan2
- F13A1 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 97/262 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs142954620, COSV99342345; called by muse, mutect2, varscan2
- FAF2 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 202/561 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs146584253; called by muse, mutect2, varscan2
- FAM102A | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs1266946381, COSV100305415; called by muse, mutect2, varscan2
- FAM120C | c.1850G>T p.R617M | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100069649; called by muse, mutect2, varscan2
- FAM124B | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as rs1274115593, COSV99706244; called by muse, mutect2, varscan2
- FAM131C | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 93/288 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs374242693; called by muse, mutect2, varscan2
- FAM135A | c.3146C>T p.T1049M (on ENST00000370479 / NM_001351599.1; = p.T836M on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs778399413, COSV99525336; called by muse, mutect2, varscan2
- FAM169A | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.123); catalogued as rs1022925315, COSV65847020; called by muse, mutect2, varscan2
- FAM171A1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1290535497, COSV65313996, COSV65318878; called by muse, mutect2, varscan2
- FAM184A | c.2855G>A p.R952Q | Missense Mutation (SNP) | VAF 203/564 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs772242066, COSV58859418; called by muse, mutect2, varscan2
- FAM209A | c.180G>A p.W60* | Nonsense Mutation (SNP) | VAF 176/440 reads (40%) | catalogued as COSV99711178; called by muse, mutect2, varscan2
- FAM20A | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 23/128 reads (18%) | catalogued as rs367720325, CM132164; called by muse, mutect2, varscan2
- FAM222B | c.1288A>G p.T430A | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.986); catalogued as COSV100368246; called by muse, mutect2, varscan2
- FAM83D | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as COSV99465033; called by muse, mutect2, varscan2
- FAM9A | c.220G>T p.G74* | Nonsense Mutation (SNP) | VAF 69/95 reads (73%) | catalogued as COSV101121308; called by muse, mutect2, varscan2
- FANCC | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs371897078, COSV56657712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASN | c.5557G>A p.V1853I | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs527759350, COSV60751334; called by muse, varscan2
- FASTKD5 | c.2243G>A p.R748H | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs376790179, COSV53910347; called by muse, mutect2, varscan2
- FAT1 | c.7366G>A p.A2456T | Missense Mutation (SNP) | VAF 113/315 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs370340394; called by muse, mutect2, varscan2
- FAT2 | c.9761G>A p.R3254H | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs1460826520, COSV55821206, COSV99941630; called by muse, varscan2
- FAT2 | c.5650C>T p.P1884S | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1007832890, COSV55832186, COSV99941857; called by muse, mutect2, varscan2
- FAT4 | c.7267G>A p.A2423T | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs776977766, COSV58679491; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT4 | c.11939A>G p.Y3980C | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58674254; called by muse, mutect2, varscan2
- FBL | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 86/217 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.876); catalogued as rs762429726, COSV55681501; called by muse, mutect2, varscan2
- FBLIM1 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs145692215, COSV60028713; called by muse, mutect2, varscan2
- FBLN5 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 80/228 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1287925034, COSV50902297, COSV99969376; called by muse, varscan2
- FBN1 | c.3758A>T p.Q1253L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV100354117; called by muse, mutect2, varscan2
- FBN1 | c.1972C>T p.R658W | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751517759, COSV57323743; called by muse, mutect2, varscan2
- FBRS | c.610G>A p.V204I (on ENST00000287468; = p.V724I on NM_001105079.3) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs765730952, COSV54914854; called by muse, varscan2
- FBXO10 | c.1759G>A p.G587S | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1462132253, COSV99446292; called by muse, mutect2, varscan2
- FBXO27 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs141960657; called by muse, mutect2, varscan2
- FBXO31 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); catalogued as COSV100291276; called by muse, varscan2
- FBXO42 | c.1343C>T p.T448M | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as rs561367398, COSV100981662; called by muse, mutect2, varscan2
- FBXW11 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.123); catalogued as rs1314572527, COSV99439879; called by muse, mutect2, varscan2
- FCGBP | c.11443C>T p.R3815W | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs750656477; called by muse, mutect2, varscan2
- FCHO1 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99405857; called by muse, mutect2
- FCHSD1 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs766305911, COSV71300793; called by muse, mutect2, varscan2
- FCN3 | c.670A>G p.S224G | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV99585246; called by muse, mutect2, varscan2
- FCRL4 | c.929G>A p.C310Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54860437; called by muse, mutect2
- FER1L5 | c.4916G>A p.R1639H (on ENST00000623019; = p.R1612H on NM_001293083.2) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs758225117, COSV101208812; called by muse, mutect2, varscan2
- FGD5 | c.2892G>T p.E964D | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as COSV53238723, COSV53242883; called by muse, mutect2, varscan2
- FIG4 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.031); catalogued as rs759566206, COSV57788518; called by muse, mutect2, varscan2
- FIGNL1 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs201162351, COSV63554336; called by muse, mutect2, varscan2
- FILIP1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52726622; called by muse, mutect2, varscan2
- FILIP1L | c.2822C>T p.T941M (on ENST00000354552 / NM_182909.3; = p.T701M on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 182/523 reads (35%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.475); catalogued as rs374858996, COSV58771156; called by muse, varscan2
- FKBP8 | c.932G>A p.R311H (on ENST00000222308 / NM_001308373.2; = p.R312H on NM_012181.5) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99723899; called by muse, mutect2, varscan2
- FLII | c.3722G>A p.R1241Q | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs374452292; called by muse, mutect2, varscan2
- FLII | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 78/226 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774851650, COSV100493493; called by muse, varscan2
- FLNB | c.2996G>A p.R999Q | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.311); catalogued as rs755928543, COSV99911969; called by muse, mutect2, varscan2
- FLNC | c.3295G>A p.V1099I | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.538); catalogued as rs759452636, COSV100367678; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLRT1 | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.178); catalogued as COSV99734732; called by muse, mutect2, varscan2
- FLRT3 | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99427897; called by muse, mutect2, varscan2
- FLT3 | c.2678C>T p.P893L | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.483); catalogued as rs1048919218, COSV54048706; called by muse, mutect2, varscan2
- FLT4 | c.3282G>C p.Q1094H | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV99986096; called by muse, mutect2, varscan2
- FMN1 | c.3997C>T p.R1333* (on ENST00000616417 / NM_001277313.2; = p.R1110* on NM_001103184.4) | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as rs1189166915, COSV57917773; called by muse, mutect2, varscan2
- FMNL1 | c.1585G>T p.D529Y | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100056222; called by muse, mutect2, varscan2
- FMO3 | c.1547A>G p.K516R | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV63006591; called by muse, mutect2, varscan2
- FNBP4 | c.1815G>T p.W605C | Missense Mutation (SNP) | VAF 103/298 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99771458; called by muse, mutect2, varscan2
- FNBP4 | c.521C>A p.P174H | Missense Mutation (SNP) | VAF 136/408 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99771459; called by muse, mutect2, varscan2
- FNDC1 | c.1718G>A p.G573D | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.36); catalogued as rs552629097, COSV99795074; called by muse, mutect2, varscan2
- FNDC3B | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as COSV100393691; called by muse, mutect2, varscan2
- FNDC4 | c.245A>G p.Q82R | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV99253804; called by muse, mutect2, varscan2
- FOCAD | c.4389G>C p.K1463N | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as rs1443542288, COSV100620101; called by muse, mutect2, varscan2
- FOLR1 | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100398523; called by muse, mutect2, varscan2
- FOXK1 | c.1924C>A p.L642I | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.437); catalogued as COSV100194651; called by muse, mutect2
- FOXN3 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.312); catalogued as rs1171167664, COSV99725881; called by muse, mutect2, varscan2
- FPR2 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 132/396 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.097); catalogued as COSV100389143; called by muse, mutect2, varscan2
- FRRS1 | c.1561G>A p.V521I | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.857); catalogued as rs774713001, COSV54921881; called by muse, mutect2, varscan2
- FRRS1 | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV99789712; called by muse, mutect2, varscan2
- FRY | c.7021G>A p.G2341R | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374001727; called by muse, mutect2, varscan2
- FSCN3 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | catalogued as rs146611259; called by muse, mutect2, varscan2
- FTSJ3 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 154/359 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs749097576, COSV100037196; called by muse, mutect2, varscan2
- FUT3 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 87/233 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs779913543, COSV99744298; called by muse, mutect2, varscan2
- FXR2 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as COSV100007092; called by muse, mutect2, varscan2
- FZD2 | c.1345G>A p.G449S | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV100190244; called by muse, mutect2, varscan2
- G3BP1 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1349252853, COSV100663897; called by muse, mutect2, varscan2
- GABRA6 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs766837058, COSV99194101, COSV99194103; called by muse, mutect2, varscan2
- GABRB2 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs375083192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRG2 | c.1121C>T p.A374V (on ENST00000361925 / NM_001375343.1; = p.A334V on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/716 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as rs1415043929, COSV62722149; called by muse, mutect2
- GAD1 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.149); catalogued as COSV60151756; called by muse, mutect2, varscan2
- GAD1 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs765841229, COSV64026197; called by muse, mutect2, varscan2
- GAK | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as rs1276720144, COSV58504557; called by muse, varscan2
- GALM | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99697012; called by muse, mutect2, varscan2
- GALM | c.441G>A p.W147* | Nonsense Mutation (SNP) | VAF 68/190 reads (36%) | catalogued as COSV99697017; called by muse, mutect2, varscan2
- GALNT16 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV100545750; called by muse, mutect2, varscan2
- GALNT17 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.722); catalogued as rs747182395, COSV61145814; called by muse, mutect2, varscan2
- GALNT18 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1275357638, COSV99923928; called by muse, mutect2, varscan2
- GALNT3 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs201855584, COSV101204882; called by muse, mutect2, varscan2
- GALNT3 | c.1329G>A p.W443* | Nonsense Mutation (SNP) | VAF 55/150 reads (37%) | catalogued as COSV101204883; called by muse, mutect2, varscan2
- GALNT3 | c.953A>C p.K318T | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.215); catalogued as COSV101204884; called by muse, mutect2, varscan2
- GAN | c.443A>G p.H148R | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.365); catalogued as COSV101633962; called by muse, mutect2, varscan2
- GANC | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 75/201 reads (37%) | PolyPhen probably damaging (1); catalogued as rs368575859; called by muse, mutect2, varscan2
- GAREM1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 135/379 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99330288; called by muse, mutect2, varscan2
- GATA6 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs144512170; called by muse, mutect2, varscan2
- GATB | c.788A>G p.N263S | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs372598891; called by muse, mutect2, varscan2
- GBP7 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 81/224 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV99642874; called by muse, varscan2
- GCKR | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as rs374489109, COSV53108921; called by muse, mutect2, varscan2
- GCN1 | c.7837G>A p.D2613N | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs548401692, COSV56113709; called by muse, mutect2, varscan2
- GCN1 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as rs1364643792, COSV56105417; called by muse, mutect2, varscan2
- GDF10 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs34512490; called by muse, varscan2
- GDF6 | c.1256G>A p.C419Y | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54623321; called by muse, mutect2
- GFI1B | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761729738, COSV59743876; called by muse, mutect2, varscan2
- GFRA4 | c.760C>T p.P254S (on ENST00000319242 / NM_145762.3; = p.P224S on NM_022139.4) | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV99293846; called by muse, mutect2, varscan2
- GIMAP1 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.036); catalogued as rs374968861, COSV56188394; called by muse, mutect2, varscan2
- GIMAP4 | c.813G>T p.E271D | Missense Mutation (SNP) | VAF 43/313 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as COSV99750485; called by muse, mutect2, varscan2
- GIPC2 | c.560del p.K187Rfs*7 | Frame Shift Del (DEL) | VAF 40/259 reads (15%) | catalogued as rs1557540863; called by mutect2, pindel, varscan2
- GLT6D1 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.403); catalogued as rs370842340, COSV65628678; called by muse, mutect2, varscan2
- GLUL | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100091858; called by muse, mutect2, varscan2
- GLYATL2 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 123/332 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs750660285, COSV99780226; called by muse, mutect2, varscan2
- GLYR1 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as COSV58925571; called by muse, mutect2, varscan2
- GM2A | c.37C>A p.L13M | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV64095378; called by muse, mutect2, varscan2
- GMEB2 | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs991103616, COSV56605757, COSV99823467; called by muse, mutect2, varscan2
- GMPPA | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs201361535, COSV100354522; called by muse, mutect2, varscan2
- GNA12 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV51741741; called by muse, mutect2, varscan2
- GNRHR | c.907C>A p.P303T | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.626); catalogued as COSV99892007; called by muse, mutect2, varscan2
- GOLGA2 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1204251912, COSV68597023; called by muse, mutect2
- GOLGA4 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 262/824 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as rs113898889; called by muse, mutect2, varscan2
- GOLGB1 | c.6362A>G p.E2121G | Missense Mutation (SNP) | VAF 89/220 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100510387; called by muse, mutect2, varscan2
- GOLPH3 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 126/311 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs192633198; called by muse, mutect2, varscan2
- GP2 | c.1067C>T p.A356V (on ENST00000381362 / NM_001007240.3; = p.A353V on NM_001502.4) | Missense Mutation (SNP) | VAF 90/259 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100221286; called by muse, mutect2, varscan2
- GP5 | c.601C>A p.L201I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55462011; called by muse, mutect2, varscan2
- GP5 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV55462015; called by muse, mutect2, varscan2
- GPANK1 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs746875032, COSV100788971; called by muse, mutect2, varscan2
- GPC1 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as rs763227743, COSV99882649; called by muse, varscan2
- GPHN | c.1336C>T p.R446* (on ENST00000315266 / NM_001377519.1; = p.R479* on NM_020806.5) | Nonsense Mutation (SNP) | VAF 96/235 reads (41%) | catalogued as rs778591008, COSV59472614; called by muse, mutect2, varscan2
- GPR139 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs556069972, COSV58503875; called by muse, mutect2, varscan2
- GPR26 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.034); catalogued as rs760298769, COSV99500772, COSV99500809; called by muse, mutect2, varscan2
- GPR31 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.771); catalogued as COSV100834101; called by muse, mutect2, varscan2
- GPR37L1 | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.03); catalogued as rs777374958, COSV66162864; called by muse, mutect2, varscan2
- GPR45 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.255); catalogued as COSV99306718; called by muse, mutect2, varscan2
- GPR88 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV59291829; called by muse, mutect2, varscan2
2,250 further variants in this file (1,400 protein-altering or splice-affecting, 808 silent, 42 other) are not listed here.
